Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AACC, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AACC-01A (Primary Tumor).

[page 1 of 3]
ICD O-3
Carcinoma, hepatocellular &
cholangiocarcinoma combined 818c13
Site: Liver C22.0
9/5/14

CLINICAL DIAGNOSIS: HCC

Specimen : liver

Gross Photo : 1

GROSS:

1. Specimen:

Liver:

7.4 x 4.5 x 8.0 cm, 85.0 gm and 11.0 x 6.5 x 6.5 cm, 98.0 gm, unfixed

Gallbladder:

12.0 cm in length, 4.5 cm in diameter, and 0.2 cm in thickness, unfixed

2. Tumor location: segment 6

Tumor number: one

Tumor size: 2.1 x 2.0 cm

3. Satellite nodule: no

4. Gross type

HCC: vaguely nodular

5. Tumor necrosis: yes (10 %)

6. Hemorrhage/peliosis: no

7. Portal vein invasion: no

8. Bile duct invasion: no

Gross photo present.

Blocks

RM, resection margin x 1

T1-2, tumor mass x 2

A, non-tumorous lesion x 1

GB, gallbladder x 1

MICROSCOPIC:

1. Hepatocellular carcinoma:

1-1. Differentiation

The worst differentiation II

The major differentiation I

1-2. Histologic type: trabecular

1-3. Cell type: hepatic

1-4. Fatty change: yes (10 %)

2. Cholangiocarcinoma: no

3. Combined hepatocellular and cholangiocarcinoma: no

4. Fibrous capsule formation: partial capsule

5. Capsular infiltration: yes

[page 2 of 3]
- 6. Septum formation: no
- 7. Surgical resection margin invasion: no, margin of the clearance (0.1 cm)
- 8. Serosal invasion: no
- 9. Portal vein invasion: no
- 10. Bile duct invasion: no
- 11. Hepatic vein invasion: no
- 12. Hepatic artery invasion: no
- 13. Microvessel invasion: no
- 14. Intrahepatic metastasis: no
- 15. Multicentric occurrence: no

Non-tumor liver pathology

- 1. Chronic hepatitis:
- 1-1. Etiology: HBV
- 1-2. Grade, lobular: minimal
- 1-3. Grade, portoperiportal: mild
- 1-4. Stage (fibrosis): cirrhosis
- 1-5. Cirrhosis: micronodular
- 2. Dysplastic nodule: no
- 3. Ductal epithelial dysplasia: no
- 4. Other liver diseases: no

SPECIAL STAIN:

Trichrome: positive (cirrhosis, stage IV)

NOT reported. Gross:

NOT reported. Gross:

Peritoneal fluid, smear, inflammation

Peritoneal fluid, smear, inflammation

Liver, ectomy, hepatocellular carcinoma

T56000, P10, M81703

Gallbladder, ectomy, autolysis

T57000, P10, M54001

DIAGNOSIS:

Liver, segment 6, segmentectomy:

Hepatocellular carcinoma, well differentiated

Gallbladder, cholecystectomy:

[page 3 of 3]
Autolysis

Suggestion :

Source: NCI Genomic Data Commons file 17ca2a5a-71c9-4da8-af65-07fa8d3a37d5 (TCGA-DD-AACC.0093FD02-9219-4901-8DA2-D98AEBDCF1D5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).